Somatic mutation profile of tumor specimen TCGA-D1-A1NX-01A (aliquot TCGA-D1-A1NX-01A-11D-A16D-09) from TCGA case TCGA-D1-A1NX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.9 years (24,441 days).
Specimen TCGA-D1-A1NX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fdea4a3-cee8-4c75-95db-75fb4e93ed28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1NX-10A (Blood Derived Normal), aliquot TCGA-D1-A1NX-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b836118-9e22-4cee-9c49-55db853e64f3

The open-access MAF lists 47 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 34, Silent 8, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 86/106 reads (81%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 21/24 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4128G>T p.L1376F (on ENST00000272895 / NM_173076.3; = p.L1058F on NM_015657.3) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55962354; called by muse, mutect2, varscan2
- ADAMTS20 | c.4730C>A p.S1577Y | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV67133107; called by muse, mutect2, varscan2
- ADAMTS5 | c.1691C>T p.T564M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs747675073, COSV53179146; called by muse, mutect2, varscan2
- AMBN | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV59826674; called by muse, mutect2, varscan2
- ARRDC4 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99164357; called by muse, mutect2, varscan2
- ATP13A1 | c.636C>G p.D212E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52286926; called by muse, mutect2, varscan2
- ATXN1 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs764842057, COSV55219119, COSV99788247; called by muse, mutect2, varscan2
- BDP1 | c.2978C>G p.S993C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV62431962; called by muse, mutect2, varscan2
- C18orf54 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1310463958, COSV55618335, COSV55618571; called by muse, mutect2, varscan2
- CABYR | c.482_485del p.V161Dfs*19 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as COSV59111292; called by mutect2, pindel, varscan2
- CAPN13 | c.1127A>C p.Q376P | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV54431734; called by muse, mutect2, varscan2
- CHEK2 | c.868G>A p.A290T (on ENST00000382580 / NM_001005735.2; = p.A247T on NM_007194.4) | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60421427; called by muse, mutect2, varscan2
- DNAH10 | c.5825G>T p.G1942V (on ENST00000409039; = p.G1881V on NM_207437.3) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68995256; called by muse, mutect2, varscan2
- DNAH8 | c.13145T>C p.V4382A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59452968; called by muse, mutect2, varscan2
- DSC1 | c.830C>G p.T277S | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as COSV57146586; called by muse, mutect2, varscan2
- FBN1 | c.7192A>C p.T2398P | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.368); catalogued as COSV57319445; called by muse, mutect2, varscan2
- FGF5 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 58/122 reads (48%) | catalogued as rs201539600, COSV56889450; called by muse, mutect2, varscan2
- GABPB2 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as COSV100927327, COSV64460985; called by muse, mutect2, varscan2
- HMCN1 | c.4129C>G p.L1377V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV54907339; called by muse, mutect2, varscan2
- KLK7 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58344395; called by muse, mutect2, varscan2
- LAMB1 | c.1583A>G p.Q528R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55965943; called by muse, mutect2, varscan2
- MPV17L | c.371A>C p.N124T | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as COSV55008598; called by muse, mutect2, varscan2
- MROH2B | c.4035G>A p.M1345I | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs377219425; called by muse, mutect2, varscan2
- OR2Y1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs373477986; called by muse, mutect2, varscan2
- PALB2 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55165949; called by muse, mutect2, varscan2
- PCDHGA8 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.021); catalogued as COSV53892732; called by muse, mutect2, varscan2
- PRKG2 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52324977, COSV52325502; called by muse, mutect2, varscan2
- SLC25A27 | c.798-1G>C p.X266_splice | Splice Site (SNP) | VAF 38/85 reads (45%) | catalogued as COSV64928280; called by muse, mutect2, varscan2
- SLC9C2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs539570027, COSV62946320, COSV62947742; called by muse, mutect2, varscan2
- SPEM2 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.059); catalogued as COSV60366970; called by muse, mutect2, varscan2
- SSH1 | c.2385T>G p.N795K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58457008; called by muse, mutect2, varscan2
- SV2A | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV64964270, COSV64966153; called by muse, mutect2, varscan2
- TPO | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV61103416; called by muse, mutect2, varscan2
- TSPEAR | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs1425457705, COSV59957782, COSV59960387; called by muse, mutect2, varscan2
- ZFP64 | c.1513G>T p.V505L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53800204; called by muse, mutect2, varscan2
- ZFYVE16 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV62016035; called by muse, mutect2, varscan2
- ZNF267 | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as COSV56253568; called by muse, mutect2, varscan2
- ANGEL1 | c.627C>T p.P209= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs375438066, COSV51873768; called by muse, mutect2, varscan2
- CDIP1 | c.141G>A p.A47= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs758918388, COSV54860527; called by muse, mutect2, varscan2
- EGFLAM | c.510C>T p.S170= | Silent (SNP) | VAF 35/68 reads (51%) | catalogued as rs571639364, COSV59305186; called by muse, mutect2, varscan2
- IL18R1 | c.126G>A p.S42= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs56183212; called by muse, mutect2, varscan2
- KIF5A | c.2952C>T p.G984= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs1369446897, COSV54055504; called by muse, mutect2, varscan2
- MIB2 | c.1029G>A p.A343= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs548568909, COSV100598739; called by muse, mutect2, varscan2
- PCDHGA12 | c.594C>T p.R198= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1273946805, COSV52754583; called by muse, mutect2, varscan2
- RYR1 | c.852C>A p.V284= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV62099811; called by muse, mutect2, varscan2
